Somatic mutation profile of tumor specimen TCGA-55-7727-01A (aliquot TCGA-55-7727-01A-11D-2167-08) from TCGA case TCGA-55-7727, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.0 years (25,929 days).
Specimen TCGA-55-7727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b05be39-3c52-4e17-93d6-1a9c622c73d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7727-10A (Blood Derived Normal), aliquot TCGA-55-7727-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c75ce350-402d-4d1e-959e-e7a62c83f6c3

The open-access MAF lists 270 somatic variants for this specimen: 199 protein-altering or splice-affecting, 66 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 66, Nonsense Mutation 13, Frame Shift Del 4, Splice Site 4, Intron 2, Translation Start Site 1, 3'UTR 1, Splice Region 1, In Frame Del 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1057519786, COSV51691446, COSV51693647, COSV51695114; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACACB | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58139339; called by muse, mutect2, varscan2
- ACLY | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs367736290; called by muse, mutect2
- ADAMTS16 | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1261919529, COSV56976515, COSV56996915; called by muse, mutect2
- AGR3 | c.450A>T p.L150= | Splice Region (SNP) | VAF 22/84 reads (26%) | catalogued as COSV60038660; called by muse, mutect2, varscan2
- AHR | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV54124652, COSV99620223; called by muse, mutect2, varscan2
- ANKRD26 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV65796196; called by muse, mutect2, varscan2
- AQP7 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53023455; called by muse, mutect2
- ASAP1 | c.3134A>G p.N1045S | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as rs1322197928, COSV63051282; called by muse, mutect2, varscan2
- ASTN2 | c.1567G>A p.E523K (on ENST00000313400 / NM_001365069.1; = p.E472K on NM_014010.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57794282; called by muse, mutect2
- ATRN | c.3322+1G>T p.X1108_splice | Splice Site (SNP) | VAF 17/125 reads (14%) | catalogued as COSV53530267, COSV53531674; called by muse, mutect2, varscan2
- ATRNL1 | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV61809256; called by muse, mutect2, varscan2
- BUB3 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs755166457, COSV60593074; called by muse, mutect2, varscan2
- BUD13 | c.851G>C p.R284T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV52769230; called by muse, mutect2, varscan2
- C3orf20 | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV53786846; called by muse, mutect2, varscan2
- CACNA1B | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV53135316; called by muse, mutect2, varscan2
- CCDC141 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as COSV55377149; called by muse, mutect2
- CCDC178 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV55760721; called by muse, mutect2, varscan2
- CCDC18 | c.2018C>T p.S673F (on ENST00000343253 / NM_001306076.1; = p.S674F on NM_206886.4) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV58145185; called by muse, mutect2, varscan2
- CCDC54 | c.40A>T p.R14W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53759162; called by muse, mutect2, varscan2
- CCR6 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs145768514, COSV59475612; called by muse, mutect2, varscan2
- CDCA5 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV51870199; called by muse, mutect2
- CDH9 | c.811A>T p.S271C | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV50331773; called by muse, mutect2, varscan2
- CEACAM5 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV55751783; called by muse, mutect2
- CHD5 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs751825704, COSV52419335; called by muse, mutect2, varscan2
- CHRD | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV52609875; called by muse, mutect2, varscan2
- CIAO1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51498386; called by muse, mutect2
- CLCA4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); catalogued as COSV55369511; called by muse, mutect2
- CLEC1B | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046061, COSV53725976; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by muse, mutect2, varscan2
- CNTNAP4 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56689756; called by muse, mutect2, varscan2
- COL9A1 | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs769216302, COSV57887525; called by muse, mutect2, varscan2
- CPXCR1 | c.570C>A p.H190Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV52162554, COSV52163325; called by muse, mutect2, varscan2
- CUL4A | c.1702C>T p.Q568* (on ENST00000375440 / NM_001008895.4; = p.Q468* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV58374161; called by muse, mutect2, varscan2
- CYFIP2 | c.44A>C p.D15A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV59044271; called by muse, mutect2
- DAB1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as COSV59731451; called by mutect2, varscan2
- DHX9 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV62360595; called by muse, mutect2, varscan2
- DNAJC22 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67712418; called by muse, mutect2, varscan2
- DOT1L | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101288704; called by muse, mutect2
- DYNLRB2 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV58416574; called by muse, mutect2, varscan2
- E4F1 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV57039949; called by muse, mutect2, varscan2
- EGR2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.491); catalogued as COSV54346108; called by muse, mutect2, varscan2
- ENTPD7 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs1209459742, COSV65112642; called by muse, mutect2, varscan2
- EPHA1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV51973006; called by muse, mutect2, varscan2
- EPS15 | c.2322G>C p.K774N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65543537; called by muse, mutect2, varscan2
- ERCC6L2 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV56632288; called by muse, mutect2
- ERICH3 | c.4463C>A p.P1488Q | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1293991565, COSV58601486; called by muse, mutect2, varscan2
- FAM71B | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57229927; called by muse, mutect2
- FAM89A | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV64166343; called by muse, mutect2, varscan2
- FASN | c.5378G>T p.G1793V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60757449; called by mutect2, varscan2
- FASTKD3 | c.1563T>A p.F521L | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52950589; called by muse, mutect2
- FASTKD5 | c.2085G>A p.M695I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53907289; called by muse, mutect2
- FRS2 | c.27T>A p.D9E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.069); catalogued as COSV54727654; called by muse, mutect2, varscan2
- FUT1 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308920240, COSV59569113; called by muse, mutect2, varscan2
- GABRG1 | c.432G>C p.W144C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54957483; called by muse, mutect2, varscan2
- GABRG3 | c.1135C>A p.L379M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.657); catalogued as COSV100407960; called by muse, mutect2, varscan2
- GABRQ | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs77796656, COSV64782969; called by muse, mutect2, varscan2
- GEN1 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58057454; called by muse, mutect2, varscan2
- GJA8 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53788064, COSV99569011; called by muse, mutect2, varscan2
- GNAZ | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV50739668; called by muse, mutect2, varscan2
- GPR158 | c.2145+1G>A p.X715_splice | Splice Site (SNP) | VAF 16/100 reads (16%) | catalogued as COSV66275292; called by muse, mutect2, varscan2
- GPR75 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/153 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61829464; called by muse, mutect2, varscan2
- GPRC6A | c.2265G>C p.M755I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59954173; called by muse, mutect2, varscan2
- GPX1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV69043064; called by muse, mutect2, varscan2
- GRM8 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58808200; called by muse, mutect2, varscan2
- GRN | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50007881; called by muse, mutect2
- HEATR5A | c.5392G>C p.E1798Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV66343112; called by muse, mutect2
- HMCN1 | c.16268C>T p.S5423F | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54916045; called by muse, mutect2
- IGLV1-47 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs977926845; called by muse, mutect2, varscan2
- IGSF22 | c.2501A>G p.Y834C (on ENST00000319338; = p.Y935C on NM_173588.4) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV55011241; called by muse, mutect2
- IL36B | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.281); catalogued as COSV52087466, COSV99034981; called by muse, mutect2, varscan2
- INTS4 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs747921947, COSV71088089, COSV71089797; called by muse, mutect2, varscan2
- ITK | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101439837, COSV70063573; called by muse, mutect2, varscan2
- JAK2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV67596272, COSV67632399; called by muse, mutect2, varscan2
- JARID2 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV59192387; called by muse, mutect2, varscan2
- KCNH2 | c.3328C>G p.Q1110E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.258); catalogued as COSV51206730; called by muse, mutect2
- KIAA0895 | c.421C>T p.P141S (on ENST00000297063 / NM_001100425.2; = p.P90S on NM_015314.3) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as COSV51712023; called by muse, mutect2, varscan2
- KIF2B | c.1919G>T p.R640L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV52132788; called by muse, mutect2, varscan2
- KLHL38 | c.1336G>T p.V446L | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58088158; called by muse, mutect2, varscan2
- KLHL4 | c.1685C>A p.T562K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64144654; called by muse, mutect2, varscan2
- LAMP5 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55717004, COSV99855551; called by muse, mutect2, varscan2
- LARGE1 | c.676G>T p.V226F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV61665681; called by muse, mutect2, varscan2
- LGI2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 29/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771116317, COSV66122458; called by muse, mutect2, varscan2
- LRP10 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV62078553; called by muse, mutect2, varscan2
- LRRC4C | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.688); catalogued as COSV53431195; called by muse, mutect2, varscan2
- LRRC7 | c.3924G>A p.W1308* (on ENST00000651989 / NM_001370785.2; = p.W1275* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV50507053; called by muse, mutect2, varscan2
- LTB4R | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV99350826; called by muse, mutect2, varscan2
- LZTFL1 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV56111182, COSV56111773; called by muse, mutect2, varscan2
- MARS2 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56571773; called by muse, mutect2, varscan2
- MEF2C | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60934543; called by muse, mutect2, varscan2
- MKI67 | c.7130G>A p.R2377K | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV64075429; called by muse, mutect2, varscan2
- MTERF3 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV54633471; called by muse, mutect2
- MUC16 | c.25504C>G p.P8502A | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.235); catalogued as COSV67478052; called by muse, mutect2, varscan2
- MUC17 | c.7888G>A p.E2630K | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as COSV60294980; called by muse, mutect2, varscan2
- MUC17 | c.10066G>A p.E3356K | Missense Mutation (SNP) | VAF 14/411 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as COSV60294986; called by muse, mutect2
- MYNN | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62991651; called by muse, mutect2, varscan2
- NALCN | c.4597G>A p.V1533I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV51948025; called by muse, mutect2, varscan2
- NAV3 | c.708T>A p.S236R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.092); catalogued as COSV57093934; called by muse, mutect2, varscan2
- NBEA | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV59800266; called by muse, mutect2, varscan2
- NCAM1 | c.1392G>C p.K464N (on ENST00000316851 / NM_181351.5; = p.K454N on NM_000615.7) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57520020; called by muse, mutect2, varscan2
- NCAN | c.3286C>A p.Q1096K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV53054051; called by muse, mutect2, varscan2
- NCOA1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV56048183; called by muse, mutect2
- NDUFB9 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52675475; called by mutect2, varscan2
- NEK1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV71456805; called by muse, mutect2
- NET1 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV100742307; called by muse, mutect2, varscan2
- NET1 | c.195+1G>T p.X65_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100742308; called by muse, mutect2, varscan2
- NIBAN3 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56311197, COSV99962815; called by muse, mutect2, varscan2
- NLRC5 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV52658773; called by muse, mutect2, varscan2
- NOX4 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.232); catalogued as rs772288710, COSV54458060; called by muse, mutect2, varscan2
- NPBWR2 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs1342743111, COSV100871125, COSV100871155; called by mutect2, varscan2
- NPL | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51125019; called by muse, mutect2, varscan2
- NPR2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV61312575; called by muse, mutect2, varscan2
- NPRL2 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51602924; called by muse, mutect2
- OR10K1 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 125/283 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV56872887; called by muse, mutect2, varscan2
- OR1Q1 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV52918457, COSV52919158; called by muse, mutect2, varscan2
- OR2T6 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV63216677; called by muse, mutect2
- OR4A16 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV59042711, COSV59044047; called by muse, mutect2, varscan2
- OR5F1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.917); catalogued as COSV53547394; called by muse, mutect2, varscan2
- OR6X1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV60010069; called by muse, mutect2, varscan2
- PBLD | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV53266555; called by muse, mutect2, varscan2
- PCDH15 | c.3143T>C p.L1048P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.917); catalogued as COSV57311440, COSV57346173; called by muse, mutect2, varscan2
- PCDH15 | c.1890G>T p.R630S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV57271263, COSV57346202; called by muse, mutect2, varscan2
- PCDH17 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931719, COSV100932160; called by muse, mutect2, varscan2
- PCDH19 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99720036; called by muse, mutect2
- PCDHA7 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs1554136059, COSV65337511; called by muse, mutect2, varscan2
- PCDHB6 | c.1786C>A p.Q596K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV99170242; called by mutect2, varscan2
- PCDHGA12 | c.2331C>G p.D777E | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV52757984; called by muse, mutect2
- PCDHGA6 | c.998T>A p.V333D | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53982110; called by muse, mutect2, varscan2
- PDGFRA | c.3245A>G p.D1082G | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV57270543; called by muse, mutect2, varscan2
- PDGFRB | c.632-1G>T p.X211_splice | Splice Site (SNP) | VAF 15/110 reads (14%) | catalogued as COSV55807339; called by muse, mutect2, varscan2
- PGR | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); catalogued as COSV54805253; called by muse, mutect2, varscan2
- PHC1 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV70418319; called by muse, mutect2
- PIK3AP1 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV59534345; called by muse, mutect2, varscan2
- PLPPR4 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780153127, COSV64564776; called by mutect2, varscan2
- PLXNA2 | c.3001A>G p.M1001V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1189456798, COSV65442432; called by muse, mutect2, varscan2
- PLXND1 | c.3213C>G p.I1071M | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60716008; called by muse, mutect2
- PLXND1 | c.2876C>G p.S959* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV60716025, COSV60718016; called by muse, mutect2, varscan2
- PRAMEF15 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 32/833 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1441632021; called by muse, mutect2
- PRDM7 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57987237; called by muse, mutect2, varscan2
- PSG8 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140447066, COSV100126336; called by muse, mutect2, varscan2
- PTGFR | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs755551230, COSV66115775; called by muse, mutect2, varscan2
- PTPRD | c.4913G>C p.G1638A | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV61949297, COSV61984282; called by muse, mutect2, varscan2
- PXDNL | c.3287G>T p.G1096V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62492597; called by muse, mutect2, varscan2
- QSOX2 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62394585; called by mutect2, varscan2
- RAP1B | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV51669434; called by muse, mutect2, varscan2
- RBM10 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61308787; called by muse, mutect2
- RBM12B | c.2087A>C p.E696A | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV67898403; called by muse, mutect2, varscan2
- RIPPLY3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61566879; called by muse, mutect2, varscan2
- RSRC2 | c.835G>T p.V279F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV59205876; called by muse, mutect2
- RYR2 | c.5160G>A p.M1720I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV63693244; called by muse, mutect2, varscan2
- SALL3 | c.3188T>C p.M1063T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1415699917, COSV73306216; called by muse, mutect2, varscan2
- SAMD15 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV53626990; called by muse, mutect2, varscan2
- SCYL2 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.065); catalogued as COSV62569585; called by muse, mutect2, varscan2
- SDC4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65595678; called by muse, mutect2, varscan2
- SEPTIN4 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV58728453; called by muse, mutect2, varscan2
- SERPINB7 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs900031047, COSV60534755; called by mutect2, varscan2
- SETBP1 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV56328511; called by muse, mutect2, varscan2
- SETX | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749077874, COSV56389119; called by muse, mutect2, varscan2
- SH3BGRL2 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs778281298, COSV100877640, COSV63964854; called by muse, mutect2
- SIGLEC11 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as rs748192530, COSV70221956; called by muse, mutect2, varscan2
- SIPA1L2 | c.1029A>T p.E343D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV53394112; called by muse, mutect2
- SLC38A10 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55846889; called by muse, mutect2, varscan2
- SMAD4 | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as CD075558, COSV61685403, COSV61688028; called by muse, mutect2, varscan2
- SMYD4 | c.2209A>G p.S737G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59712211; called by muse, mutect2, varscan2
- SNX9 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs747192131, COSV67585070; called by muse, mutect2
- SPATA31D1 | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1232103621, COSV61197088, COSV61198206; called by muse, mutect2, varscan2
- SRCAP | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV99350437; called by mutect2, varscan2
- ST6GAL1 | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | PolyPhen probably damaging (1); catalogued as COSV51471618; called by muse, mutect2, varscan2
- STARD13 | c.1439A>G p.D480G (on ENST00000336934 / NM_001243476.3; = p.D362G on NM_052851.3) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV55233300; called by muse, mutect2, varscan2
- SV2A | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 4/53 reads (8%) | catalogued as rs1266904330, COSV64964417; called by muse, mutect2
- SYCP2L | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51655064; called by muse, mutect2, varscan2
- TAS2R41 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.248); catalogued as COSV68765553; called by muse, mutect2, varscan2
- TBX20 | c.342T>A p.H114Q | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV68784476; called by muse, mutect2, varscan2
- TDRD6 | c.3916A>T p.K1306* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV60176819; called by muse, mutect2, varscan2
- TMEM169 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55265899; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 75/191 reads (39%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRIM71 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67471732; called by muse, mutect2, varscan2
- TYRO3 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55484724; called by muse, mutect2, varscan2
- UACA | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.743); catalogued as rs766014158, COSV59857441; called by muse, mutect2, varscan2
- UMODL1 | c.1655A>T p.E552V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV61160870; called by muse, mutect2, varscan2
- USH2A | c.4108G>A p.V1370I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV56395970; called by muse, mutect2, varscan2
- USP51 | c.1862T>C p.M621T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72351782; called by muse, mutect2, varscan2
- VWC2 | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as COSV100514376; called by muse, mutect2
- XRN1 | c.3292G>A p.D1098N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53814484; called by muse, mutect2, varscan2
- XRN2 | c.1652G>A p.R551K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as COSV65867888, COSV65870485; called by muse, mutect2, varscan2
- ZNF202 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60247656; called by muse, mutect2, varscan2
- ZNF229 | c.672G>C p.W224C | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV52163372, COSV52163788; called by muse, mutect2, varscan2
- ZNF354A | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100234532; called by muse, mutect2, varscan2
- ZNF718 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68140516; called by muse, mutect2, varscan2
- ZNF862 | c.1346A>G p.E449G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as rs1013456804, COSV56224807; called by muse, mutect2, varscan2
- ZP2 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV54815100; called by muse, mutect2, varscan2
- ZSWIM4 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54323781; called by muse, mutect2, varscan2
- BOD1L1 | c.3501_3520del p.L1167Ffs*9 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel
- FRG2C | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- IGHV1OR21-1 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10Q1 | c.161_190del p.C54_M63del | In Frame Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel
- PIEZO2 | c.7429del p.S2477Lfs*18 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- STYXL2 | c.2483_2485delinsAT p.A828Dfs*6 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | called by mutect2*, pindel, varscan2*
- ZAN | c.6054del p.A2019Pfs*35 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- ACSM2A | c.1503A>T p.R501= (on ENST00000219054; = p.R422= on NM_001308169.2) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV54586788; called by muse, mutect2, varscan2
- ADAM20 | c.120A>G p.P40= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs761900874, COSV56455226; called by muse, mutect2
- ADAMTSL1 | c.2923A>C p.R975= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV65894454; called by muse, mutect2, varscan2
- ADGRF4 | c.54C>A p.S18= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV51954397; called by muse, mutect2, varscan2
- ANK1 | c.345G>T p.L115= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99225629; called by muse, mutect2, varscan2
- ARAF | c.642C>T p.S214= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99283285; called by muse, mutect2, varscan2
- ARHGDIB | c.561C>T p.L187= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs1384791917, COSV56763958; called by muse, mutect2, varscan2
- ASAP1 | c.1746C>G p.V582= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs1290045106, COSV63051292; called by muse, mutect2, varscan2
- ASTN2 | c.1686C>A p.P562= (on ENST00000313400 / NM_001365069.1; = p.P511= on NM_014010.5) | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV57794264; called by muse, mutect2
- B3GALNT1 | c.385T>C p.L129= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV57580695; called by muse, mutect2
- BCL2 | c.553C>T p.L185= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV61385876; called by muse, mutect2, varscan2
- CACNA1H | c.4605C>T p.F1535= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as rs1182140794, COSV61996599; called by muse, mutect2
- CLVS1 | c.969G>T p.L323= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV57978383; called by muse, mutect2, varscan2
- CORIN | c.465G>T p.T155= | Silent (SNP) | VAF 23/140 reads (16%) | catalogued as COSV56694663; called by muse, mutect2, varscan2
- CTPS2 | c.180C>G p.V60= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV63723239; called by muse, mutect2, varscan2
- CXADR | c.66C>T p.I22= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV53028262, COSV53029926; called by muse, mutect2
- CXXC1 | c.1920G>A p.T640= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs943888762, COSV53275649; called by muse, mutect2, varscan2
- DCAF4L2 | c.645G>T p.T215= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as COSV60479814, COSV60480247, COSV60482124; called by muse, mutect2, varscan2
- DCDC1 | c.2673T>A p.L891= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60308845; called by muse, mutect2, varscan2
- EHMT2 | c.1932G>A p.R644= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV64996881; called by muse, mutect2
- ELOF1 | c.96G>A p.E32= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs761001102, COSV52947931; called by muse, mutect2, varscan2
- GLUD2 | c.711T>C p.A237= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV60152419; called by muse, mutect2, varscan2
- GNAO1 | c.111C>A p.L37= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52616690; called by muse, mutect2, varscan2
- HOOK3 | c.1425G>A p.K475= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV56884617; called by muse, mutect2, varscan2
- HROB | c.1305A>G p.T435= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs370671551, COSV55370147; called by muse, mutect2, varscan2
- HSPA12B | c.1173C>T p.F391= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53924602; called by muse, varscan2
- KCNJ8 | c.783G>A p.L261= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53717258; called by muse, mutect2, varscan2
- LGR6 | c.2490C>T p.F830= (on ENST00000367278 / NM_001017403.1; = p.F778= on NM_021636.3) | Silent (SNP) | VAF 34/317 reads (11%) | catalogued as COSV55160876; called by muse, mutect2, varscan2
- LRRC52 | c.471C>T p.L157= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV54232744; called by muse, mutect2
- LRRC8C | c.1491C>T p.S497= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs765276218, COSV64999456; called by muse, mutect2, varscan2
- MAGEC1 | c.3180C>T p.P1060= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV53575222, COSV53576705, COSV53580517; called by muse, mutect2
- MPDZ | c.5907G>T p.G1969= (on ENST00000319217 / NM_001330637.2; = p.G1940= on NM_003829.5) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs776198912, COSV59920386; called by muse, mutect2, varscan2
- MROH2B | c.4047C>A p.I1349= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV101270607, COSV68186501; called by muse, mutect2, varscan2
- MUC16 | c.17763G>A p.V5921= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV67478058; called by muse, mutect2, varscan2
- MYPN | c.3525G>T p.L1175= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV62732600, COSV62735585; called by muse, mutect2, varscan2
- NAALAD2 | c.648C>A p.I216= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58959115; called by muse, mutect2, varscan2
- NIBAN3 | c.459G>T p.T153= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV56311160; called by muse, mutect2, varscan2
- NME9 | c.696C>A p.L232= (on ENST00000333911 / NM_001349024.2; = p.L171= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/215 reads (7%) | catalogued as COSV58620288; called by muse, mutect2
- NUDT5 | c.573C>T p.L191= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100036473; called by muse, mutect2, varscan2
- OBSCN | c.1305C>T p.G435= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs1192247107, COSV52749702; called by muse, mutect2
- OR1C1 | c.351G>A p.V117= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV101376189, COSV68715967; called by muse, mutect2, varscan2
- OR2C3 | c.507G>T p.L169= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV63575554; called by muse, mutect2, varscan2
- OR2G3 | c.813G>A p.G271= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV60682370; called by muse, mutect2, varscan2
- PAK5 | c.1431G>A p.V477= | Silent (SNP) | VAF 15/153 reads (10%) | catalogued as COSV62031915; called by muse, mutect2
- PCNP | c.420A>G p.P140= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54576769; called by muse, mutect2, varscan2
- PDCD11 | c.3708A>T p.R1236= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV63934480; called by muse, mutect2, varscan2
- PIGQ | c.1788G>A p.T596= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs150021665; called by muse, mutect2, varscan2
- PKD1L2 | c.2046C>G p.L682= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55160159, COSV55165160; called by muse, mutect2, varscan2
- PLEKHG1 | c.963C>T p.Y321= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs781601317, COSV62048914; called by muse, mutect2, varscan2
- POLA2 | c.1053A>T p.T351= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV55484495; called by muse, mutect2, varscan2
- PRKD1 | c.300G>A p.K100= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV59576158, COSV59576388; called by muse, mutect2, varscan2
- PSG8 | c.447C>T p.P149= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV100126333; called by muse, mutect2, varscan2
- R3HDM2 | c.2901G>T p.L967= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60415044; called by muse, mutect2, varscan2
- SAXO1 | c.456G>A p.E152= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs754908911, COSV65870827; called by muse, mutect2, varscan2
- SCN5A | c.4686G>A p.K1562= (on ENST00000333535 / NM_198056.3; = p.K1561= on NM_000335.5) | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs1377024124, COSV61130999; called by muse, mutect2
- SLC12A5 | c.1260C>A p.T420= (on ENST00000454036 / NM_001134771.2; = p.T397= on NM_020708.5) | Silent (SNP) | VAF 132/390 reads (34%) | catalogued as COSV54796840; called by muse, mutect2, varscan2
- SLC4A5 | c.795A>G p.A265= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100697748; called by mutect2, varscan2
- SLC5A4 | c.216C>A p.A72= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV56671873; called by muse, mutect2, varscan2
- SNAI2 | c.231C>T p.S77= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV50079581; called by muse, mutect2
- TF | c.54G>T p.L18= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53921798; called by muse, mutect2, varscan2
- TMEM67 | c.1695G>T p.V565= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV60041790; called by muse, mutect2, varscan2
- TRIM31 | c.642G>A p.G214= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV65059389; called by muse, mutect2
- TYROBP | c.207T>A p.P69= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV52888138; called by muse, mutect2, varscan2
- VWC2 | c.661C>A p.R221= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100514377; called by muse, mutect2
- WDR33 | c.1614A>G p.Q538= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1222221612, COSV59252045; called by muse, mutect2, varscan2
- ZNF804A | c.3426A>T p.S1142= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV56457658; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149730 C>A | 5'Flank (SNP) | VAF 5/24 reads (21%) | catalogued as rs1033897993; called by muse, mutect2, varscan2
- CACNA1C | c.1481+547G>A | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100219558; called by muse, mutect2, varscan2
- CCDC32 | c.-1A>T | 5'UTR (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100785968; called by muse, mutect2, varscan2
- TCF3 | c.1823-422G>T | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as COSV53652408; called by muse, mutect2, varscan2
- TMPRSS11E | c.*1G>A | 3'UTR (SNP) | VAF 20/128 reads (16%) | catalogued as rs1164227435, COSV100542409; called by muse, mutect2, varscan2
